Somatic mutation profile of tumor specimen C3L-02399-01 (aliquot CPT0171090011) from CPTAC case C3L-02399, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 72.3 years (26,413 days).
Specimen C3L-02399-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9977290-7dc8-49a5-a866-022e60e778bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02399-71 (Blood Derived Normal), aliquot CPT0171120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b8abdf9-6b7d-4f8c-8d92-18415d9d7889

The open-access MAF lists 823 somatic variants for this specimen: 558 protein-altering or splice-affecting, 162 silent, 103 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 400, Silent 162, Frame Shift Del 81, Intron 57, Nonsense Mutation 29, Frame Shift Ins 19, 3'UTR 13, Splice Region 13, Splice Site 12, RNA 11, 5'UTR 8, 3'Flank 7.

Variants (750 of 823; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.7714-2A>G p.X2572_splice | Splice Site (SNP) | VAF 188/474 reads (40%) | catalogued as rs886041976; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 6/116 reads (5%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, mutect2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 32/235 reads (14%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 24/79 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FH | c.668_669del p.K223Rfs*26 | Frame Shift Del (DEL) | VAF 40/426 reads (9%) | catalogued as rs886039364; ClinVar: pathogenic; called by mutect2, pindel
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 47/121 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 102/284 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM983500, COSV64289544, COSV64299563; called by muse, varscan2
- PTEN | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 142/317 reads (45%) | catalogued as rs786202918, CM981673, COSV100910801, COSV64288504; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD15 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); catalogued as rs899069152, COSV56196457; called by muse, mutect2, varscan2
- ABL1 | c.1877G>A p.G626D | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.206); catalogued as rs1253014415, COSV59326426; ClinVar: uncertain significance; called by muse, varscan2
- ADAM23 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1275659625; called by muse, mutect2, varscan2
- ADAR | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs761708272, COSV52721287; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAT1 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs762132802; called by muse, mutect2, varscan2
- ADGRA2 | c.1573del p.A525Pfs*12 | Frame Shift Del (DEL) | VAF 36/218 reads (17%) | catalogued as rs760256806, COSV59443632; called by mutect2, pindel, varscan2
- ADO | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs771278566; called by muse, mutect2, varscan2
- ADPGK | c.1235A>G p.Q412R | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.481); catalogued as COSV100295185; called by muse, mutect2
- AHCTF1 | c.6428C>T p.P2143L (on ENST00000366508; = p.P2117L on NM_015446.5) | Missense Mutation (SNP) | VAF 81/269 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.32); catalogued as rs546280276; called by muse, mutect2, varscan2
- ALS2CL | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.478); catalogued as rs756342748, COSV59670131; called by muse, mutect2
- AMER1 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 20/480 reads (4%) | catalogued as COSV57659668; called by muse, mutect2
- AMER3 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs562674707, COSV58467104; called by muse, mutect2, varscan2
- AMPH | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs368302578; called by muse, mutect2
- ARAF | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV51694703; called by muse, mutect2, varscan2
- ARAP3 | c.2286del p.R763Gfs*27 | Frame Shift Del (DEL) | VAF 28/204 reads (14%) | catalogued as rs747599520; called by mutect2, varscan2
- ARFGEF2 | c.3673A>G p.I1225V | Missense Mutation (SNP) | VAF 133/321 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.107); catalogued as rs1181492172; called by muse, mutect2, varscan2
- ARHGEF17 | c.5029G>A p.A1677T | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV55236150; called by muse, mutect2
- ARMC5 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 26/345 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs781190027; called by muse, mutect2
- ASL | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 71/552 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146123574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATIC | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 38/265 reads (14%) | catalogued as rs1025725483, COSV52694765; called by muse, mutect2, varscan2
- ATM | c.8256C>G p.I2752M | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1555128574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A1 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 119/251 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as rs778662261, COSV62869892; called by muse, mutect2, varscan2
- BBX | c.2524C>T p.R842W (on ENST00000325805 / NM_001142568.3; = p.R812W on NM_020235.7) | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs376586358; called by muse, mutect2, varscan2
- BCHE | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.193); catalogued as COSV52263526; called by muse, mutect2, varscan2
- BTAF1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765162182, COSV56438162, COSV99795959; called by muse, mutect2, varscan2
- BTBD17 | c.940C>A p.R314S | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV100945364; called by muse, mutect2, varscan2
- C7orf25 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100623607; called by muse, mutect2
- CACFD1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.217); catalogued as rs782678068, COSV52469040; called by muse, mutect2
- CACNA1F | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 173/441 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs138447882, CM099067; called by muse, mutect2, varscan2
- CAMK2G | c.1538G>C p.R513P (on ENST00000423381 / NM_001367518.1; = p.R450P on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 132/332 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55213523; called by muse, mutect2, varscan2
- CARD6 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs199835164, COSV54564127; called by muse, mutect2, varscan2
- CATSPERD | c.1509G>A p.S503= | Splice Region (SNP) | VAF 11/92 reads (12%) | catalogued as rs766707672, COSV58464186; called by muse, mutect2, varscan2
- CCDC120 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 121/251 reads (48%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.553); catalogued as rs990990503, COSV64480804; called by muse, mutect2, varscan2
- CCDC166 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.74); catalogued as rs781940688; called by muse, mutect2
- CCDC188 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.497); catalogued as rs886269550; called by muse, mutect2, varscan2
- CCDC85B | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs970230123, COSV57027506; called by muse, mutect2, varscan2
- CCNI2 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); catalogued as rs1380193828; called by muse, mutect2, varscan2
- CDK14 | c.1163A>G p.Y388C (on ENST00000380050 / NM_001287135.2; = p.Y370C on NM_012395.3) | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs149042459; called by muse, mutect2, varscan2
- CDKL1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs762377622, COSV53583338; called by muse, mutect2, varscan2
- CDKN2C | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 17/230 reads (7%) | catalogued as rs781400938, COSV52954198; called by muse, mutect2
- CDNF | c.437A>G p.E146G | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV101012376; called by muse, mutect2, varscan2
- CEP57L1 | c.822+1G>T p.X274_splice | Splice Site (SNP) | VAF 94/240 reads (39%) | catalogued as rs760454702; called by muse, mutect2, varscan2
- CEP85L | c.1738G>A p.V580I | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as rs773520622; called by muse, mutect2, varscan2
- CFAP126 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 50/511 reads (10%) | catalogued as rs746183973, COSV61367697; called by muse, mutect2
- CFAP46 | c.7486G>A p.A2496T | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs376500318; called by muse, mutect2
- CHRNA1 | c.367del p.I123Ffs*67 (on ENST00000261007 / NM_001039523.3; = p.I98Ffs*67 on NM_000079.4) | Frame Shift Del (DEL) | VAF 64/369 reads (17%) | catalogued as rs753250273; called by mutect2, varscan2
- CNGB3 | c.1514C>T p.T505M | Missense Mutation (SNP) | VAF 142/320 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs755207461, COSV60691782; called by mutect2, varscan2
- COL1A1 | c.1299C>T p.S433= | Splice Region (SNP) | VAF 77/165 reads (47%) | catalogued as rs776229611; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORO6 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as rs765504035, COSV61471803; called by muse, mutect2, varscan2
- CORO7 | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV52029801; called by muse, mutect2
- CORO7 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774571246; called by muse, mutect2, varscan2
- COX16 | c.165del p.K55Nfs*2 | Frame Shift Del (DEL) | VAF 46/118 reads (39%) | catalogued as rs759241200; called by mutect2, varscan2
- CPXM2 | c.1628C>A p.P543H | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs781155643, COSV53857764; called by muse, mutect2, varscan2
- CSH2 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); catalogued as rs1348047158; called by muse, mutect2, varscan2
- CSNK1G2 | c.769-3C>T | Splice Region (SNP) | VAF 35/255 reads (14%) | catalogued as rs1309580045; called by muse, mutect2, varscan2
- CXCL1 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs201545716; called by muse, mutect2, varscan2
- CXorf66 | c.516del p.K172Nfs*2 | Frame Shift Del (DEL) | VAF 110/318 reads (35%) | catalogued as rs1288889313; called by mutect2, varscan2
- CYP27C1 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs771424479, COSV58866780; called by muse, mutect2, varscan2
- DDB1 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs376616995; called by muse, mutect2, varscan2
- DDX54 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as rs750051631; called by muse, mutect2, varscan2
- DEFB118 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | catalogued as rs750510475, COSV53620107; called by mutect2, varscan2
- DGAT1 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453106665; called by muse, mutect2
- DHX36 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1200601058; called by muse, mutect2
- DHX40 | c.1412A>G p.D471G | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs1177596134; called by muse, mutect2, varscan2
- DIS3 | c.2477A>G p.Y826C | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs904553704, COSV66706090; called by muse, mutect2
- DMRTB1 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 114/280 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.716); catalogued as rs762915457, COSV101008284; called by mutect2, varscan2
- DOCK2 | c.3682C>T p.R1228C | Missense Mutation (SNP) | VAF 27/271 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.974); catalogued as rs753671821; called by muse, mutect2, varscan2
- DOCK5 | c.5466del p.S1824Afs*80 | Frame Shift Del (DEL) | VAF 57/182 reads (31%) | catalogued as rs34013556; called by mutect2, pindel, varscan2
- DOP1A | c.3271A>G p.M1091V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs374062903; called by muse, mutect2, varscan2
- DROSHA | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 66/228 reads (29%) | catalogued as rs749032311, COSV60782123; called by muse, mutect2, varscan2
- DTX3L | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1373763460, COSV99950101; called by muse, mutect2
- ELAVL1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 126/312 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs757692680, COSV60967799; called by muse, mutect2, varscan2
- ENPEP | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV54458768; called by muse, mutect2, varscan2
- EPB41 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV100548440; called by muse, mutect2
- EPB41L4A | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as rs778624919, COSV54866208; called by muse, mutect2
- EPHB4 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 112/421 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs34653459; called by muse, mutect2, varscan2
- ERCC4 | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 34/691 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777184889, COSV61314123; called by muse, mutect2
- ERCC6L2 | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as rs761294202; called by muse, mutect2, varscan2
- ESPN | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.019); catalogued as rs770260337; called by muse, mutect2, varscan2
- FANCD2 | c.2825C>T p.T942M | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs776311610, COSV99812242; called by muse, mutect2, varscan2
- FASTKD2 | c.1409A>G p.Y470C | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs771381837; called by muse, mutect2, varscan2
- FBN2 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104390298, COSV99330509; called by muse, mutect2, varscan2
- FCRL5 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV62515146; called by muse, mutect2, varscan2
- FSCB | c.2293G>A p.V765M | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as rs1293814314, COSV100469212; called by muse, mutect2, varscan2
- FSIP2 | c.12079C>T p.R4027W | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1038299138; called by muse, mutect2, varscan2
- FTSJ3 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100037302; called by muse, mutect2
- GAPDHS | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs967166360, COSV55884150, COSV99722854; called by muse, mutect2
- GJD2 | c.362del p.P121Lfs*4 | Frame Shift Del (DEL) | VAF 41/319 reads (13%) | catalogued as rs748483263, COSV51749500; called by mutect2, pindel, varscan2
- GLUL | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 91/489 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100092189; called by muse, mutect2, varscan2
- GMIP | c.979del p.R327Afs*47 | Frame Shift Del (DEL) | VAF 68/173 reads (39%) | catalogued as rs1340785895; called by mutect2, pindel, varscan2
- GOLIM4 | c.1179G>A p.V393= | Splice Region (SNP) | VAF 80/156 reads (51%) | catalogued as COSV58329941; called by muse, varscan2
- GP9 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs780671537, COSV100264691; called by muse, mutect2, varscan2
- GPR18 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.95); catalogued as rs776777158; called by muse, mutect2
- H2AC8 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.667); catalogued as rs1317626199; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 15/110 reads (14%) | catalogued as rs755016625; called by mutect2, varscan2
- HPS3 | c.2814A>C p.K938N | Missense Mutation (SNP) | VAF 54/329 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52834844; called by muse, mutect2, varscan2
- IFT27 | c.80G>T p.S27I (on ENST00000433985 / NM_001363003.2; = p.S26I on NM_006860.5) | Missense Mutation (SNP) | VAF 137/312 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99067850; called by muse, mutect2, varscan2
- IGSF9 | c.2084G>A p.R695H (on ENST00000368094 / NM_001135050.2; = p.R679H on NM_020789.4) | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765405500; called by muse, mutect2
- IL16 | c.3276del p.K1092Nfs*6 (on ENST00000302987 / NM_172217.5; = p.K391Nfs*6 on NM_004513.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/207 reads (11%) | catalogued as rs777448128; called by mutect2, pindel, varscan2
- INTS1 | c.2527del p.R843Gfs*11 | Frame Shift Del (DEL) | VAF 24/135 reads (18%) | catalogued as rs779930616; called by mutect2, varscan2
- IRF9 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60702640; called by muse, mutect2
- ISM2 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV53633878; called by muse, mutect2, varscan2
- KAT6B | c.3761G>A p.R1254H | Missense Mutation (SNP) | VAF 120/328 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs568525923, COSV54741444; called by muse, varscan2
- KDM3B | c.2132C>G p.T711S | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs767361238; called by muse, varscan2
- KDM5C | c.3220C>T p.Q1074* | Nonsense Mutation (SNP) | VAF 12/316 reads (4%) | catalogued as rs1556835903; called by muse, mutect2
- KDM6A | c.3337G>A p.V1113I | Missense Mutation (SNP) | VAF 89/351 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.245); catalogued as rs367925808, COSV100938566, COSV65039087, COSV65040590, COSV65042618, COSV65043755; called by muse, mutect2, varscan2
- KIAA0825 | c.3071G>T p.R1024L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs762888155; called by muse, mutect2, varscan2
- KIAA1549L | c.3455T>C p.I1152T (on ENST00000321505; = p.I1449T on NM_012194.3) | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1460952962; called by muse, mutect2, varscan2
- KLF16 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 103/570 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759591358, COSV51736606; called by muse, mutect2, varscan2
- KLF3 | c.654del p.L219* | Frame Shift Del (DEL) | VAF 20/107 reads (19%) | catalogued as rs1260051731; called by mutect2, pindel, varscan2
- KMT2B | c.1656dup p.K553Qfs*46 | Frame Shift Ins (INS) | VAF 16/112 reads (14%) | catalogued as rs775294431; called by mutect2, varscan2
- KMT2B | c.3602del p.P1201Rfs*154 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as COSV55870773; called by mutect2, pindel, varscan2
- KMT2D | c.6354del p.A2119Lfs*25 | Frame Shift Del (DEL) | VAF 63/163 reads (39%) | catalogued as COSV56474038; called by mutect2, pindel, varscan2
- KRT84 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 63/455 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs773953337; called by muse, mutect2, varscan2
- LDLR | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.104); catalogued as rs763233960, CD042208, CM014574, CM055373, COSV52942707, COSV52943244; ClinVar: likely benign; called by muse, mutect2, varscan2
- LHX9 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 18/391 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV61332234; called by muse, mutect2
- LILRB4 | c.1227G>T p.Q409H (on ENST00000391733 / NM_001278428.3; = p.Q408H on NM_001278426.3) | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV54403775; called by muse, varscan2
- LMAN1 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 60/227 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs201253101; called by muse, mutect2, varscan2
- LMTK2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51995056; called by muse, mutect2
- LRRC7 | c.3620A>G p.N1207S (on ENST00000651989 / NM_001370785.2; = p.N1174S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); catalogued as rs776261353; called by muse, mutect2, varscan2
- LSM10 | c.362dup p.N121Kfs*3 | Frame Shift Ins (INS) | VAF 11/102 reads (11%) | catalogued as rs768776995; called by mutect2, pindel, varscan2
- LSM14A | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs752826786; called by muse, mutect2, varscan2
- LYST | c.44A>G p.D15G | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs773170266, COSV67706371; called by muse, mutect2, varscan2
- LZTR1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs935736801, COSV53151511; called by muse, mutect2
- MACROH2A2 | c.438dup p.K147Efs*21 | Frame Shift Ins (INS) | VAF 35/148 reads (24%) | catalogued as rs775088830; called by mutect2, varscan2
- MAK16 | c.234G>T p.W78C | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100789446; called by muse, mutect2, varscan2
- MATN3 | c.871T>C p.C291R | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447636211; called by muse, mutect2, varscan2
- MDGA2 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 60/443 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs748391283, COSV67811984; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs750092100; called by mutect2, varscan2
- MESP2 | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs748629363; called by muse, mutect2, varscan2
- MEX3D | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.346); catalogued as rs780987625; called by muse, mutect2
- MFAP5 | c.171A>G p.T57= | Splice Region (SNP) | VAF 23/78 reads (29%) | catalogued as rs756057687; called by muse, mutect2, varscan2
- MIGA1 | c.1188+10dup | Splice Region (INS) | VAF 9/64 reads (14%) | catalogued as rs764028419; called by mutect2, varscan2
- MLH3 | c.3676G>A p.A1226T | Missense Mutation (SNP) | VAF 139/470 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747817741, COSV99470248; called by muse, mutect2, varscan2
- MOGS | c.881del p.P294Lfs*11 | Frame Shift Del (DEL) | VAF 77/347 reads (22%) | catalogued as rs750486813; called by mutect2, pindel, varscan2
- MROH2A | c.4100G>A p.S1367N | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs1416807618; called by muse, mutect2
- MS4A3 | c.215T>C p.L72S | Missense Mutation (SNP) | VAF 27/316 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.592); catalogued as rs910175184; called by muse, mutect2
- MT3 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 58/307 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs754570773, COSV99570462; called by muse, mutect2, varscan2
- MTHFD2 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.059); catalogued as rs1386669400, COSV51202503; called by muse, mutect2, varscan2
- MTNR1B | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs760459053; called by muse, mutect2, varscan2
- MYO15A | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 106/652 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV52768022; called by muse, varscan2
- MYO15A | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 59/410 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs576041753, COSV52759636; ClinVar: uncertain significance; called by muse, varscan2
- NCLN | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.183); catalogued as rs910529847; called by muse, mutect2
- NDST2 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 143/318 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779485278, COSV55217803; called by muse, mutect2, varscan2
- NLGN4X | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 73/277 reads (26%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs1180614483, COSV99321341; called by muse, mutect2, varscan2
- NLRP8 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs779904625, COSV99405675; called by muse, mutect2, varscan2
- NOS1 | c.2027dup p.C677Lfs*38 | Frame Shift Ins (INS) | VAF 32/118 reads (27%) | catalogued as rs746543323; called by mutect2, varscan2
- NOS1 | c.583A>G p.S195G | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1245463007; called by muse, mutect2, varscan2
- NT5C1B | c.575G>T p.R192L (on ENST00000359846 / NM_001199086.2; = p.R132L on NM_033253.4) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.338); catalogued as COSV58399195; called by muse, mutect2, varscan2
- NTS | c.305T>C p.L102S | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.911); catalogued as rs1437312943; called by muse, mutect2, varscan2
- NUP155 | c.484C>T p.R162* (on ENST00000231498 / NM_153485.3; = p.R103* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 30/265 reads (11%) | catalogued as rs765177729, COSV51527298; called by muse, mutect2, varscan2
- OLFM1 | c.1232C>T p.T411M (on ENST00000371793 / NM_001282611.2; = p.T393M on NM_014279.5) | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767622547, COSV53277197, COSV53278980; called by muse, mutect2, varscan2
- OR5J2 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as rs753110839, COSV56620439; called by muse, mutect2, varscan2
- OR5T1 | c.122T>A p.L41* | Nonsense Mutation (SNP) | VAF 57/131 reads (44%) | catalogued as COSV57303028; called by muse, mutect2, varscan2
- PARP1 | c.520C>G p.P174A | Missense Mutation (SNP) | VAF 156/879 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV100828595; called by muse, mutect2, varscan2
- PCDHA3 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 64/818 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); catalogued as rs782560612, COSV63539730; called by muse, mutect2
- PCDHB7 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 289/664 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV50756781; called by muse, mutect2, varscan2
- PCF11 | c.249C>A p.N83K | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53530887; called by muse, mutect2, varscan2
- PCM1 | c.6003G>A p.M2001I | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as rs1273969576, COSV59585620; called by muse, mutect2, varscan2
- PF4V1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 85/205 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV99896333; called by muse, mutect2, varscan2
- PFAS | c.3210G>T p.E1070D | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs543768607; called by muse, mutect2, varscan2
- PHYH | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 71/473 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1261804897; called by muse, mutect2, varscan2
- PIGO | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1163633984; called by muse, mutect2
- PITX2 | c.704C>T p.P235L (on ENST00000354925 / NM_001204397.1; = p.P242L on NM_000325.6) | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1301721326, COSV60740837; called by muse, mutect2
- PKD1 | c.11172G>A p.W3724* (on ENST00000262304 / NM_001009944.3; = p.W3723* on NM_000296.4) | Nonsense Mutation (SNP) | VAF 34/590 reads (6%) | catalogued as CM143934; called by muse, mutect2
- PKD1 | c.10048A>G p.K3350E | Missense Mutation (SNP) | VAF 26/787 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.408); catalogued as CM1313898; called by muse, mutect2
- PKHD1 | c.5567C>A p.S1856* | Nonsense Mutation (SNP) | VAF 52/322 reads (16%) | catalogued as COSV61871639; called by muse, mutect2, varscan2
- PLD3 | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 167/393 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs763673552; called by muse, mutect2, varscan2
- PPM1D | c.1535del p.N512Ifs*2 | Frame Shift Del (DEL) | VAF 114/312 reads (37%) | catalogued as rs763475304; called by mutect2, pindel, varscan2
- PPP1R14A | c.87del p.L30Cfs*54 | Frame Shift Del (DEL) | VAF 35/266 reads (13%) | catalogued as rs751874633; called by mutect2, pindel, varscan2
- PPP2R2B | c.742C>T p.R248W (on ENST00000394409; = p.R314W on NM_181674.2) | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs750629860, COSV100356215, COSV60751679; called by muse, mutect2, varscan2
- PRDM15 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 13/314 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.244); catalogued as rs1159408992, COSV54152401; called by muse, mutect2
- PRKAR1B | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as rs774298132; called by muse, mutect2, varscan2
- PTAFR | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs1190531918; called by muse, mutect2, varscan2
- PTPN23 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1398239891, COSV55543372; called by muse, mutect2
- RAB3GAP1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 136/455 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.603); catalogued as COSV51479931; called by muse, mutect2, varscan2
- RAD21 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1259968025; called by muse, mutect2, varscan2
- RBL1 | c.431del p.L144* | Frame Shift Del (DEL) | VAF 27/205 reads (13%) | catalogued as COSV60328025; called by mutect2, pindel, varscan2
- RGMA | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1462747055, COSV61233509; called by muse, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 81/222 reads (36%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KL1 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376736810; called by muse, mutect2, varscan2
- RRBP1 | c.1882_1884del p.K628del (on ENST00000377813 / NM_001365613.2; = p.K198del on NM_004587.3) | In Frame Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs746356116; called by pindel, varscan2
- RSPH14 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761454900, COSV53271374, COSV99321078; called by muse, mutect2, varscan2
- SBF2 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.782); catalogued as rs751319241; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCAPER | c.3934C>T p.R1312W | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1386545920, COSV61309905; called by muse, mutect2
- SCARF2 | c.2187del p.L731Cfs*213 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | catalogued as rs370859341; called by mutect2, pindel, varscan2
- SCLT1 | c.1620dup p.A541Sfs*11 | Frame Shift Ins (INS) | VAF 26/54 reads (48%) | catalogued as rs760494753; called by mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 39/164 reads (24%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEC31A | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs781481399; called by muse, mutect2, varscan2
- SEMA3C | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1323018126; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | catalogued as rs750651342; called by mutect2, varscan2
- SERPINI2 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV52987071; called by muse, mutect2, varscan2
- SEZ6L2 | c.1759G>A p.G587S (on ENST00000308713 / NM_001114099.3; = p.G517S on NM_012410.4) | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs773920897; called by muse, mutect2, varscan2
- SH2D4B | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs771907480, COSV57894022; called by muse, mutect2, varscan2
- SHOX2 | c.545C>T p.A182V (on ENST00000441443 / NM_006884.3; = p.A206V on NM_003030.4) | Missense Mutation (SNP) | VAF 21/245 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101273841; called by muse, mutect2
- SLC10A6 | c.326del p.G109Afs*21 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | catalogued as rs753933531, COSV56721805; called by mutect2, pindel
- SLC17A5 | c.846G>T p.W282C | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV63287414; called by muse, mutect2
- SLC23A1 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 111/271 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100811943; called by muse, mutect2, varscan2
- SLC29A3 | c.1169T>C p.I390T | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as rs751891503; called by muse, mutect2, varscan2
- SLC29A4 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs773399486, COSV99786613; called by muse, mutect2, varscan2
- SLC4A9 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 34/518 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs753835738; called by muse, mutect2
- SLF2 | c.2360del p.L787* | Frame Shift Del (DEL) | VAF 14/145 reads (10%) | catalogued as rs1007972651, COSV53275602; called by mutect2, pindel, varscan2
- SMARCA2 | c.2935C>T p.R979C | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs1306474481, COSV61814217; called by muse, mutect2, varscan2
- SMOX | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.251); catalogued as rs767516409, COSV53864977; called by muse, mutect2
- SOD3 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 79/515 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs1356356589; called by muse, mutect2, varscan2
- SORBS2 | c.3130del p.E1044Nfs*65 (on ENST00000284776 / NM_021069.5; = p.E610Nfs*65 on NM_003603.6) | Frame Shift Del (DEL) | VAF 33/234 reads (14%) | catalogued as rs772549791, COSV52996321; called by mutect2, pindel, varscan2
- SORCS3 | c.3118C>A p.P1040T | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100865387; called by muse, mutect2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 32/114 reads (28%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPTBN1 | c.6916A>G p.I2306V | Missense Mutation (SNP) | VAF 24/345 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as COSV63338408; called by muse, mutect2
- STAB1 | c.4015del p.V1339Cfs*252 | Frame Shift Del (DEL) | VAF 66/175 reads (38%) | catalogued as rs761841917, COSV100402435; called by mutect2, pindel, varscan2
- STRADA | c.725C>T p.P242L (on ENST00000336174 / NM_001363786.1; = p.P205L on NM_153335.6) | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs745400938, COSV55561544; called by muse, mutect2, varscan2
- SURF6 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1365332070; called by muse, mutect2, varscan2
- SYMPK | c.3787G>A p.E1263K | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.905); catalogued as rs1368751708; called by muse, mutect2, varscan2
- SYNGR3 | c.300C>A p.D100E | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs569721806; called by muse, mutect2
- TACC2 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1199400051, COSV57755723; called by muse, mutect2, varscan2
- TFPI2 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs751463825, COSV55989782; called by muse, mutect2, varscan2
- THSD7B | c.3767C>T p.T1256M (on ENST00000272643; = p.T1254M on NM_001316349.2) | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs753240436; called by muse, mutect2, varscan2
- TMEM125 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1227452469; called by muse, mutect2
- TMEM161B | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV56931402; called by muse, mutect2
- TMTC3 | c.1242A>G p.I414M | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV99898166; called by muse, mutect2, varscan2
- TNIP1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.496); catalogued as rs1171257818, COSV59306937; called by muse, mutect2, varscan2
- TNRC18 | c.4381A>G p.K1461E | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1390284233; called by muse, mutect2, varscan2
- TOLLIP | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55135782; called by muse, mutect2, varscan2
- TRIM33 | c.1522C>G p.Q508E | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); catalogued as COSV61825282; called by muse, mutect2
- TRIM65 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 51/299 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs776566521; called by muse, mutect2, varscan2
- TRIM67 | c.2222C>A p.P741H | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64158628; called by muse, mutect2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 18/150 reads (12%) | catalogued as rs752676391; called by mutect2, varscan2
- TRMT2A | c.1208G>T p.R403L | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV52813413; called by muse, varscan2
- TRMT2B | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 28/582 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100105089; called by muse, mutect2
- TSHR | c.2101C>T p.R701C | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as rs137908024; called by muse, mutect2
- TTC34 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs1250430165; called by muse, mutect2, varscan2
- TTC7B | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60633160; called by muse, mutect2
- TTN | c.34885C>A p.P11629T (on ENST00000591111; = p.P10702T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/290 reads (7%) | PolyPhen benign (0.295); catalogued as COSV60184559, COSV60195363; called by muse, mutect2
- TTR | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 32/520 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52701242; called by muse, mutect2
- TUBB4A | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 160/649 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.376); catalogued as COSV51169782; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 48/132 reads (36%) | catalogued as rs760251146; called by mutect2, varscan2
- TXNRD1 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 72/433 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs1417226779, COSV71220796; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 22/156 reads (14%) | catalogued as COSV51954201; called by mutect2, varscan2
- USP26 | c.1044del p.F348Lfs*7 | Frame Shift Del (DEL) | VAF 28/150 reads (19%) | catalogued as CM077651, COSV63708747; called by mutect2, varscan2
- USP41 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.468); catalogued as rs544864681; called by muse, mutect2
- VSTM1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs780069475, COSV99057110; called by muse, mutect2
- WDR87 | c.8159del p.K2720Rfs*57 | Frame Shift Del (DEL) | VAF 36/234 reads (15%) | catalogued as rs1555756562; called by mutect2, varscan2
- WNT10B | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536694627, COSV56404859, COSV56405318; called by muse, mutect2, varscan2
- YIF1A | c.391dup p.R131Pfs*8 | Frame Shift Ins (INS) | VAF 16/124 reads (13%) | catalogued as rs761507279; called by mutect2, varscan2
- YTHDF1 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV64833016; called by muse, mutect2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 43/105 reads (41%) | catalogued as rs751577786; called by mutect2, varscan2
- ZDHHC15 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 149/306 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs775570770, COSV64903942; called by muse, mutect2, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | catalogued as rs781677398, COSV57709922; called by mutect2, varscan2
- ZMIZ1 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as rs142913980; called by muse, mutect2, varscan2
- ZNF337 | c.2114G>A p.R705K | Missense Mutation (SNP) | VAF 108/287 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); catalogued as COSV53320574, COSV99430562; called by muse, mutect2, varscan2
- ZNF337 | c.1864C>T p.H622Y | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs766505797, COSV53323206; called by muse, mutect2, varscan2
- ZNF581 | c.539G>C p.R180P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.753); catalogued as COSV54401163, COSV54401282; called by muse, mutect2, varscan2
- ZNF676 | c.1658C>T p.T553I (on ENST00000650058; = p.T521I on NM_001001411.3) | Missense Mutation (SNP) | VAF 17/409 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV68094069; called by muse, mutect2
- ZNF724 | c.345del p.G116Afs*22 | Frame Shift Del (DEL) | VAF 24/150 reads (16%) | catalogued as rs781412139; called by mutect2, pindel, varscan2
- ZNF837 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs535622485; called by muse, mutect2
- ZNRF3 | c.1610C>A p.S537* (on ENST00000544604 / NM_001206998.2; = p.S437* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 54/149 reads (36%) | catalogued as COSV100238758, COSV60435022; called by muse, mutect2, varscan2
- ACOT2 | c.508G>T p.V170L | Missense Mutation (SNP) | VAF 37/599 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); called by muse, mutect2
- ACTRT3 | c.877A>T p.N293Y | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACVR1C | c.1480T>C p.*494Qext*1 | Nonstop Mutation (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- ADAM30 | c.2123T>C p.F708S | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- ADAMTS1 | c.2791del p.R931Efs*3 | Frame Shift Del (DEL) | VAF 119/345 reads (34%) | called by mutect2, pindel, varscan2
- ADAMTSL4 | c.365G>C p.G122A | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.137); called by muse, mutect2
- ADGRB3 | c.4305G>A p.M1435I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ADGRG4 | c.6545T>C p.M2182T | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AEBP1 | c.1161del p.I388Lfs*57 | Frame Shift Del (DEL) | VAF 34/222 reads (15%) | called by mutect2, pindel, varscan2
- AHI1 | c.1606G>T p.G536* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- AKAP4 | c.1879T>C p.S627P | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKNA | c.4141G>T p.A1381S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AL512785.2 | c.-12+8C>T | Splice Region (SNP) | VAF 44/482 reads (9%) | called by muse, mutect2
- ANKIB1 | c.3079G>A p.A1027T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD11 | c.3659G>T p.R1220M | Missense Mutation (SNP) | VAF 41/688 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ARHGAP25 | c.1186A>G p.S396G (on ENST00000409202 / NM_001007231.3; = p.S388G on NM_014882.3) | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- ARHGEF2 | c.1630G>A p.A544T (on ENST00000361247 / NM_001162383.2; = p.A516T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/307 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.055); called by muse, mutect2
- ARHGEF26 | c.440del p.P147Rfs*19 | Frame Shift Del (DEL) | VAF 34/169 reads (20%) | called by pindel, varscan2
- ARHGEF40 | c.2011A>G p.S671G | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- ARR3 | c.761A>G p.E254G | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ASB17 | c.817A>G p.M273V | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASB4 | c.1238T>C p.L413S | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ASCC2 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 18/391 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATG2B | c.4796del p.G1599Efs*9 | Frame Shift Del (DEL) | VAF 38/206 reads (18%) | called by mutect2, pindel, varscan2
- ATP11B | c.1113dup p.I372Yfs*6 | Frame Shift Ins (INS) | VAF 23/137 reads (17%) | called by mutect2, pindel, varscan2
- ATP6V0A4 | c.934T>C p.C312R | Missense Mutation (SNP) | VAF 252/620 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- BAHCC1 | c.5708G>T p.C1903F | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, varscan2
- BCAM | c.920A>G p.Q307R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BCL6 | c.1809A>T p.K603N | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.292); called by muse, mutect2
- BCORL1 | c.2905del p.Q969Rfs*6 | Frame Shift Del (DEL) | VAF 58/182 reads (32%) | called by mutect2, pindel, varscan2
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 60/302 reads (20%) | called by mutect2, pindel, varscan2
- C11orf87 | c.342del p.L115Cfs*162 | Frame Shift Del (DEL) | VAF 98/241 reads (41%) | called by mutect2, pindel, varscan2
- CACNA1C | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAMSAP1 | c.1680del p.R561Gfs*7 | Frame Shift Del (DEL) | VAF 121/284 reads (43%) | called by mutect2, pindel, varscan2
- CAMTA1 | c.3635C>T p.T1212I | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.462); called by muse, mutect2
- CARMIL1 | c.792A>T p.Q264H | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CBFA2T3 | c.26G>T p.R9M | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CBR1 | c.143A>C p.Q48P | Missense Mutation (SNP) | VAF 61/307 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- CCDC168 | c.2785C>G p.H929D | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCDC27 | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 17/374 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2
- CCHCR1 | c.1799-1G>A p.X600_splice | Splice Site (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- CCNK | c.1332C>G p.Y444* | Nonsense Mutation (SNP) | VAF 69/291 reads (24%) | called by muse, mutect2, varscan2
- CD79B | c.432A>T p.G144= | Splice Region (SNP) | VAF 222/527 reads (42%) | called by muse, mutect2, varscan2
- CDC42BPB | c.4436A>T p.Y1479F | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.163); called by muse, mutect2
- CDK5R2 | c.422del p.G141Afs*64 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- CEMP1 | c.620A>G p.K207R | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHADL | c.722del p.P241Rfs*50 | Frame Shift Del (DEL) | VAF 21/118 reads (18%) | called by mutect2, pindel, varscan2
- CHD9 | c.2461del p.I821* | Frame Shift Del (DEL) | VAF 31/108 reads (29%) | called by mutect2, pindel, varscan2
- CHD9 | c.4174A>G p.I1392V | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CHRNA2 | c.340-1G>A p.X114_splice | Splice Site (SNP) | VAF 7/137 reads (5%) | called by muse, mutect2
- CIITA | c.1808T>A p.L603H | Missense Mutation (SNP) | VAF 156/585 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLEC17A | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- CNOT7 | c.103A>G p.N35D | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2
- COL4A1 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 16/447 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPA5 | c.824A>T p.K275M | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CPS1 | c.4330A>G p.K1444E | Missense Mutation (SNP) | VAF 96/224 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- CR1 | c.3879G>T p.K1293N | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CRIP2 | c.197-1G>T p.X66_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- CRX | c.322_323insA p.P108Hfs*66 | Frame Shift Ins (INS) | VAF 27/81 reads (33%) | called by mutect2, pindel, varscan2
- CSMD1 | c.5622A>G p.S1874= (on ENST00000520002; = p.S1873= on NM_033225.6) | Splice Region (SNP) | VAF 27/164 reads (16%) | called by muse, mutect2, varscan2
- CSPP1 | c.3428G>A p.G1143E (on ENST00000676605; = p.G1102E on NM_024790.6) | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 190/544 reads (35%) | called by mutect2, pindel, varscan2
- CTNND2 | c.979T>C p.S327P | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CUL5 | c.1694del p.N565Ifs*18 | Frame Shift Del (DEL) | VAF 42/112 reads (38%) | called by mutect2, varscan2
- DDX3X | c.1181A>G p.D394G (on ENST00000399959; = p.D395G on NM_001356.5) | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2
- DDX43 | c.1286C>T p.T429I | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLL1 | c.1933C>T p.Q645* | Nonsense Mutation (SNP) | VAF 22/274 reads (8%) | called by muse, mutect2
- DMXL1 | c.2146T>G p.L716V | Missense Mutation (SNP) | VAF 17/313 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- DNAH1 | c.708C>G p.D236E | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAH17 | c.10609C>G p.H3537D | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNALI1 | c.155T>C p.L52P (on ENST00000296218; = p.L30P on NM_003462.5) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- DOCK2 | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- DOCK7 | c.5709A>C p.K1903N (on ENST00000635253 / NM_001367561.1; = p.K1872N on NM_033407.3) | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- DSC1 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- DSEL | c.2648del p.F883Sfs*29 | Frame Shift Del (DEL) | VAF 94/264 reads (36%) | called by mutect2, pindel, varscan2
- DYRK1B | c.707T>A p.I236N | Missense Mutation (SNP) | VAF 157/378 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EBF4 | c.1123C>T p.R375W (on ENST00000609451; = p.R371W on NM_001110514.1) | Missense Mutation (SNP) | VAF 15/452 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ECEL1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 124/293 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- EEF2 | c.772A>G p.K258E | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- EIF3J | c.180del p.E61Rfs*5 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | called by mutect2, varscan2
- EIF4ENIF1 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 70/179 reads (39%) | called by muse, mutect2, varscan2
- ENTPD7 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2
- EPHA1 | c.2120A>T p.N707I | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- EPHA7 | c.1714A>G p.M572V | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ERLIN1 | c.725del p.K242Sfs*37 | Frame Shift Del (DEL) | VAF 55/141 reads (39%) | called by mutect2, pindel, varscan2
- ERO1B | c.490T>A p.F164I | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM171B | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); called by muse, mutect2
- FAM189B | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 24/367 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- FAM83B | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 99/229 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- FAM83G | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); called by muse, mutect2
- FAM8A1 | c.1173del p.Q392Sfs*10 | Frame Shift Del (DEL) | VAF 67/201 reads (33%) | called by mutect2, pindel, varscan2
- FASTK | c.1309A>T p.S437C | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2
- FAT4 | c.6241C>A p.P2081T | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXL19 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FEM1A | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FMN2 | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 9/119 reads (8%) | called by muse, mutect2
- FMR1 | c.1471+7A>G | Splice Region (SNP) | VAF 22/157 reads (14%) | called by muse, mutect2, varscan2
- FRY | c.7486A>G p.M2496V | Missense Mutation (SNP) | VAF 26/377 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.017); called by muse, mutect2
- FSIP2 | c.7697C>T p.T2566I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FUT8 | c.70del p.Y24Ifs*2 | Frame Shift Del (DEL) | VAF 25/234 reads (11%) | called by mutect2, pindel, varscan2
- GABRR3 | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- GCN1 | c.3772C>T p.Q1258* | Nonsense Mutation (SNP) | VAF 16/301 reads (5%) | called by muse, mutect2
- GIMAP8 | c.157_158dup p.S53Rfs*5 | Frame Shift Ins (INS) | VAF 104/299 reads (35%) | called by mutect2, varscan2
- GJA5 | c.200A>C p.D67A | Missense Mutation (SNP) | VAF 106/165 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GJB3 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 12/283 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- GLRA3 | c.678dup p.D227Rfs*7 | Frame Shift Ins (INS) | VAF 13/105 reads (12%) | called by mutect2, pindel, varscan2
- GLRB | c.756C>A p.Y252* | Nonsense Mutation (SNP) | VAF 40/265 reads (15%) | called by muse, mutect2, varscan2
- GNAS | c.1187_1188insA p.A397Cfs*7 | Frame Shift Ins (INS) | VAF 65/327 reads (20%) | called by mutect2, pindel, varscan2
- GPR132 | c.338T>A p.L113Q | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2
- GSPT1 | c.560_564del p.K187Rfs*3 (on ENST00000420576 / NM_001130007.2; = p.K325Rfs*3 on NM_002094.4) | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- H2AC14 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HECTD4 | c.12328A>C p.S4110R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HECTD4 | c.494_495del p.C165* | Frame Shift Del (DEL) | VAF 27/123 reads (22%) | called by mutect2, pindel, varscan2
- HIC2 | c.1250del p.G417Afs*113 | Frame Shift Del (DEL) | VAF 41/122 reads (34%) | called by mutect2, pindel, varscan2
- HLCS | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 97/378 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- HMCN1 | c.16236_16238del p.R5413del | In Frame Del (DEL) | VAF 39/332 reads (12%) | called by mutect2, pindel
- HPS4 | c.446del p.N149Tfs*26 | Frame Shift Del (DEL) | VAF 38/335 reads (11%) | called by mutect2, pindel, varscan2
- ID2 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 59/375 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IGF2R | c.6920G>A p.G2307D | Missense Mutation (SNP) | VAF 17/337 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KANK1 | c.4056T>G p.D1352E | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- KAT6B | c.3862A>G p.T1288A | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.108); called by muse, varscan2
- KDM3B | c.2048C>A p.S683* | Nonsense Mutation (SNP) | VAF 108/262 reads (41%) | called by muse, varscan2
- KIAA1210 | c.3953C>A p.P1318H | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KIAA1671 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); called by muse, mutect2
- KIAA2026 | c.5754del p.K1918Nfs*6 | Frame Shift Del (DEL) | VAF 74/189 reads (39%) | called by mutect2, pindel, varscan2
- KIF1A | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 101/282 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- KLF11 | c.464G>T p.R155M | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- KMT2C | c.12494A>G p.Q4165R | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- KPNA5 | c.621T>A p.F207L | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0.087); called by muse, varscan2
- KREMEN1 | c.241C>A p.H81N (on ENST00000407188; = p.H83N on NM_032045.5) | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KRTAP10-6 | c.316C>A p.Q106K | Missense Mutation (SNP) | VAF 54/584 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- LAMA1 | c.1997T>C p.V666A | Missense Mutation (SNP) | VAF 25/431 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- LILRB3 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 14/339 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.792); called by muse, mutect2
- LMTK2 | c.3801dup p.K1268Efs*38 | Frame Shift Ins (INS) | VAF 31/229 reads (14%) | called by mutect2, pindel, varscan2
- LORICRIN | c.196G>T p.G66W | Missense Mutation (SNP) | VAF 18/41 reads (44%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LOXL2 | c.119C>A p.P40Q | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LRFN2 | c.1265dup p.E423Gfs*8 | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- LRP3 | c.740C>A p.A247E | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LSP1 | c.421A>G p.S141G | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2
- MAG | c.512A>G p.E171G | Missense Mutation (SNP) | VAF 47/309 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MAGEB6 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- MAP3K10 | c.1980del p.A661Lfs*16 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | called by mutect2, pindel, varscan2
- MAP3K11 | c.50A>G p.N17S | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MBD6 | c.590dup p.S198Qfs*2 | Frame Shift Ins (INS) | VAF 10/74 reads (14%) | called by mutect2, pindel
- MCM8 | c.2267T>G p.F756C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- MEGF8 | c.2674G>A p.V892M (on ENST00000251268 / NM_001271938.2; = p.V825M on NM_001410.3) | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- MEX3C | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- MKS1 | c.644del p.K215Sfs*14 | Frame Shift Del (DEL) | VAF 81/498 reads (16%) | called by mutect2, pindel, varscan2
- MLH3 | c.3408A>T p.E1136D | Missense Mutation (SNP) | VAF 178/373 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, varscan2
- MLYCD | c.948+1G>A p.X316_splice | Splice Site (SNP) | VAF 32/506 reads (6%) | called by muse, mutect2
- MUC2 | c.3409T>C p.C1137R | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MYBL2 | c.1389G>T p.Q463H | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- MYH7 | c.3963G>T p.E1321D | Missense Mutation (SNP) | VAF 27/626 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- N4BP2 | c.5089C>T p.H1697Y | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NDUFAF5 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 135/780 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEB | c.12916G>A p.V4306M | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NEFM | c.2362A>G p.S788G | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2
- NEU3 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NIF3L1 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NIPBL | c.4301C>T p.A1434V | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- NKX2-1 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NKX2-4 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- NLGN2 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- NOLC1 | c.566C>A p.P189H | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- NPTX2 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- NR1H2 | c.-243G>T | Splice Region (SNP) | VAF 20/306 reads (7%) | called by muse, mutect2
- NR4A3 | c.1424del p.L475Wfs*48 | Frame Shift Del (DEL) | VAF 43/350 reads (12%) | called by mutect2, pindel, varscan2
- NRDC | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | called by mutect2, varscan2
- NRIP1 | c.866dup p.N289Kfs*8 | Frame Shift Ins (INS) | VAF 31/206 reads (15%) | called by mutect2, pindel, varscan2
- NTN4 | c.752A>C p.Y251S | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2
- OBI1 | c.776del p.N259Ifs*9 | Frame Shift Del (DEL) | VAF 15/135 reads (11%) | called by pindel, varscan2
- OBI1 | c.770T>A p.L257Q | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- OBSCN | c.4484G>A p.C1495Y | Missense Mutation (SNP) | VAF 36/593 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.942); called by muse, mutect2
- OGDH | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- OR5AP2 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PAN3 | c.1193T>C p.V398A | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); called by muse, mutect2
- PATL1 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PBX2 | c.637A>C p.S213R | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PCDHB1 | c.60del p.L21Cfs*28 | Frame Shift Del (DEL) | VAF 90/226 reads (40%) | called by mutect2, pindel, varscan2
- PDZD2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PDZD2 | c.4820G>T p.C1607F | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDZD4 | c.1699C>T p.L567F | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PDZD7 | c.2692del p.A898Pfs*22 | Frame Shift Del (DEL) | VAF 40/179 reads (22%) | called by mutect2, pindel, varscan2
- PFN3 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 67/292 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGAM4 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 126/323 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- PLCZ1 | c.854C>A p.P285Q | Missense Mutation (SNP) | VAF 14/327 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLEKHB2 | c.531_532+11del p.X177_splice (on ENST00000409279; = p.X176_splice on NM_017958.2 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 65/153 reads (42%) | called by mutect2, pindel, varscan2
- PLXNA1 | c.3051del p.Q1019Rfs*22 | Frame Shift Del (DEL) | VAF 24/181 reads (13%) | called by mutect2, pindel, varscan2
- PLXNA2 | c.1393del p.H465Mfs*57 | Frame Shift Del (DEL) | VAF 24/143 reads (17%) | called by mutect2, varscan2
- PLXNB2 | c.4387C>T p.L1463= | Splice Region (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- PLXNC1 | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2
- PNPLA8 | c.726A>C p.E242D | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- POGZ | c.2432G>A p.S811N | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- POLR1B | c.2784G>T p.M928I | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- POM121C | c.2768C>A p.P923H (on ENST00000607367; = p.P681H on NM_001099415.3) | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PPP1R12B | c.847-5G>A | Splice Region (SNP) | VAF 36/350 reads (10%) | called by muse, mutect2, varscan2
- PPP1R37 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.111); called by muse, mutect2
- PPP5C | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRH1 | c.560A>G p.Q187R | Missense Mutation (SNP) | VAF 16/341 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); called by muse, mutect2
- PRMT2 | c.856del p.S286Qfs*9 | Frame Shift Del (DEL) | VAF 35/148 reads (24%) | called by mutect2, pindel, varscan2
- PSMD3 | c.751T>A p.L251M | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PTP4A2 | c.321-2A>G p.X107_splice | Splice Site (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- PTPRC | c.3793C>G p.L1265V | Missense Mutation (SNP) | VAF 49/644 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.05); called by muse, mutect2
- RAMP3 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- RAPGEF2 | c.1385C>A p.T462N | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- RASIP1 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.488); called by muse, varscan2
- RASL12 | c.82C>A p.R28S | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.012); called by muse, mutect2
- RC3H1 | c.2617C>T p.R873* | Nonsense Mutation (SNP) | VAF 22/634 reads (3%) | called by muse, mutect2
- RFX3 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 45/363 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- RFX7 | c.1109T>C p.M370T (on ENST00000559447 / NM_001368074.1; = p.M467T on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- RGP1 | c.5T>A p.I2N | Missense Mutation (SNP) | VAF 46/359 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RGS12 | c.1271G>A p.S424N | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- RIPK1 | c.1616T>C p.I539T | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, varscan2
- RNF34 | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 46/331 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- RPP14 | c.160dup p.E54Gfs*3 | Frame Shift Ins (INS) | VAF 22/92 reads (24%) | called by mutect2, pindel, varscan2
- RRBP1 | c.3436C>T p.Q1146* (on ENST00000377813 / NM_001365613.2; = p.Q713* on NM_004587.3) | Nonsense Mutation (SNP) | VAF 23/96 reads (24%) | called by muse, mutect2, varscan2
- RTN4 | c.2007del p.V670Yfs*4 | Frame Shift Del (DEL) | VAF 21/146 reads (14%) | called by mutect2, pindel, varscan2
- SAR1A | c.438del p.K146Nfs*18 | Frame Shift Del (DEL) | VAF 24/111 reads (22%) | called by mutect2, pindel, varscan2
- SCAF4 | c.3411G>T p.K1137N | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- SCAF4 | c.749dup p.P251Tfs*2 | Frame Shift Ins (INS) | VAF 53/154 reads (34%) | called by mutect2, pindel, varscan2
- SDCBP2 | c.484G>T p.G162W (on ENST00000339987 / NM_001199784.1; = p.G77W on NM_015685.5) | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDF4 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SEC61A2 | c.1168-1G>T p.X390_splice | Splice Site (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- SEMA4B | c.1562T>A p.V521E | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEPTIN9 | c.320_331dup p.L110_S111insCTEL (on ENST00000427177 / NM_001113491.2; = p.L92_S93insCTEL on NM_006640.4) | In Frame Ins (INS) | VAF 110/350 reads (31%) | called by mutect2, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, varscan2
- SETDB1 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 22/502 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- SETDB1 | c.950-2_950-1del p.X317_splice | Splice Site (DEL) | VAF 15/149 reads (10%) | called by mutect2, pindel, varscan2
- SETX | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SFRP2 | c.781G>T p.G261* | Nonsense Mutation (SNP) | VAF 49/348 reads (14%) | called by muse, mutect2, varscan2
- SGMS1 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 14/361 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- SIGLEC10 | c.1760G>T p.R587M | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SKOR2 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 93/484 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A31 | c.477del p.G160Vfs*10 | Frame Shift Del (DEL) | VAF 45/133 reads (34%) | called by mutect2, pindel, varscan2
- SLC27A2 | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC39A4 | c.302T>C p.V101A (on ENST00000301305 / NM_001374839.1; = p.V76A on NM_017767.3) | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A1 | c.964A>G p.I322V | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC6A15 | c.1036G>T p.V346F | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- SNED1 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SOS2 | c.1069-1G>A p.X357_splice | Splice Site (SNP) | VAF 45/99 reads (45%) | called by muse, mutect2, varscan2
- SP8 | c.717del p.L240Sfs*19 (on ENST00000361443 / NM_198956.4; = p.L258Sfs*19 on NM_182700.6) | Frame Shift Del (DEL) | VAF 30/154 reads (19%) | called by mutect2, pindel, varscan2
- SPAAR | c.162_163del p.F55Hfs*60 | Frame Shift Del (DEL) | VAF 64/192 reads (33%) | called by pindel, varscan2
- SPIRE2 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPZ1 | c.599A>C p.E200A | Missense Mutation (SNP) | VAF 19/418 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2
- SRCIN1 | c.2697del p.S900Afs*4 (on ENST00000621492; = p.S866Afs*4 on NM_025248.3) | Frame Shift Del (DEL) | VAF 60/315 reads (19%) | called by mutect2, varscan2
- SRRM2 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SRSF5 | c.434dup p.N145Kfs*2 | Frame Shift Ins (INS) | VAF 51/157 reads (32%) | called by mutect2, pindel, varscan2
- STAG1 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2
- STYK1 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SUN1 | c.2346G>T p.Q782H (on ENST00000405266 / NM_001367651.1; = p.Q662H on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, mutect2
- SUPT5H | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.186); called by muse, mutect2
- SWAP70 | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYDE1 | c.1089A>C p.Q363H | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT tolerated (0.89); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- SYNE1 | c.20796G>T p.K6932N (on ENST00000367255 / NM_182961.4; = p.K6861N on NM_033071.3) | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2
- SYNE2 | c.19056+2T>C p.X6352_splice | Splice Site (SNP) | VAF 66/400 reads (17%) | called by muse, mutect2, varscan2
- TANC2 | c.4586C>A p.P1529Q | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF20 | c.4009G>A p.A1337T | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TCF20 | c.3758T>C p.M1253T | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TDRD5 | c.1907del p.L636Cfs*16 | Frame Shift Del (DEL) | VAF 84/531 reads (16%) | called by mutect2, pindel, varscan2
- TDRKH | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TES | c.512A>C p.E171A | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
- TEX10 | c.13del p.R5Efs*10 | Frame Shift Del (DEL) | VAF 23/61 reads (38%) | called by mutect2, pindel, varscan2
- TEX2 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 118/237 reads (50%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- THRA | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM231 | c.889G>A p.V297M (on ENST00000258173 / NM_001077418.3; = p.V326M on NM_001077416.2) | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- TMEM8B | c.1108C>T p.H370Y | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2
- TNFRSF6B | c.605G>A p.S202N | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAM1L1 | c.946A>T p.I316F | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TSC2 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 171/406 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- TSC2 | c.4766C>A p.P1589Q | Missense Mutation (SNP) | VAF 37/348 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC30A | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- UBE2N | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 85/190 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- UNC79 | c.4024A>G p.I1342V (on ENST00000393151 / NM_001346218.2; = p.I1165V on NM_020818.5) | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- USP45 | c.1229A>G p.D410G | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- USP9X | c.5744A>C p.E1915A | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- WAC | c.1722G>A p.W574* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- WNT4 | c.997T>A p.C333S | Missense Mutation (SNP) | VAF 139/290 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- WNT5B | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 10/165 reads (6%) | called by muse, mutect2
- WNT9A | c.1022G>A p.C341Y | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XRN1 | c.1154A>T p.K385M | Missense Mutation (SNP) | VAF 126/314 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, varscan2
- ZBTB20 | c.829C>T p.P277S (on ENST00000474710 / NM_001164342.2; = p.P204S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZC3H18 | c.2483G>A p.G828E | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZC3H7B | c.541dup p.S181Ffs*5 | Frame Shift Ins (INS) | VAF 24/158 reads (15%) | called by mutect2, pindel, varscan2
- ZFYVE9 | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- ZGRF1 | c.5884A>G p.T1962A | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- ZMYM6 | c.3603T>G p.C1201W | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ZMYND15 | c.1193del p.G398Afs*13 | Frame Shift Del (DEL) | VAF 54/255 reads (21%) | called by mutect2, pindel, varscan2
- ZNF24 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 104/282 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZNF317 | c.916T>A p.Y306N | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF324B | c.713A>G p.Q238R | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF507 | c.1334A>G p.D445G | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- ZNF512B | c.1868G>A p.C623Y | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.927); called by muse, mutect2
- ZNF726 | c.1660A>G p.T554A | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ZNF750 | c.383A>C p.Q128P | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AARS1 | c.1272G>C p.L424= | Silent (SNP) | VAF 28/615 reads (5%) | catalogued as rs1412346348, COSV55749627; called by muse, mutect2
- ABCC10 | c.1882C>T p.L628= (on ENST00000372530 / NM_001198934.2; = p.L600= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/307 reads (14%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.2670C>T p.T890= | Silent (SNP) | VAF 27/199 reads (14%) | called by muse, mutect2, varscan2
- ADGB | c.3414C>T p.R1138= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as rs914471581, COSV100828381; called by muse, mutect2, varscan2
- ANKRD52 | c.1257T>C p.P419= | Silent (SNP) | VAF 42/254 reads (17%) | called by muse, mutect2, varscan2
- ANXA8L1 | c.546C>T p.D182= | Silent (SNP) | VAF 76/525 reads (14%) | catalogued as rs1325400874; called by muse, mutect2, varscan2
- ARX | c.522G>A p.S174= | Silent (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- ATG2B | c.1086C>T p.D362= | Silent (SNP) | VAF 28/375 reads (7%) | catalogued as rs377727532; called by muse, mutect2
- ATP2A2 | c.2964C>T p.R988= | Silent (SNP) | VAF 214/517 reads (41%) | called by muse, mutect2, varscan2
- ATP2C2 | c.1122C>T p.S374= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as rs1218241601; called by muse, mutect2, varscan2
- ATP9A | c.468A>G p.Q156= | Silent (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- ATXN2 | c.2814T>C p.P938= (on ENST00000550104; = p.P778= on NM_002973.4) | Silent (SNP) | VAF 56/201 reads (28%) | called by muse, mutect2, varscan2
- B4GALT4 | c.1011A>G p.T337= | Silent (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- BCORL1 | c.816G>A p.S272= | Silent (SNP) | VAF 127/292 reads (43%) | catalogued as rs1421846849, COSV54409885; called by muse, mutect2, varscan2
- BNIP1 | c.522T>C p.N174= | Silent (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2
- BTN3A1 | c.198G>A p.K66= | Silent (SNP) | VAF 26/532 reads (5%) | called by muse, mutect2
- C11orf42 | c.135C>T p.C45= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV56410927; called by muse, mutect2, varscan2
- C20orf144 | c.324A>G p.E108= | Silent (SNP) | VAF 95/219 reads (43%) | called by muse, mutect2, varscan2
- C5orf22 | c.876T>C p.D292= | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- CAMK2A | c.498G>A p.E166= | Silent (SNP) | VAF 38/215 reads (18%) | called by muse, mutect2, varscan2
- CCDC71L | c.30C>G p.R10= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as COSV60071191; called by muse, mutect2, varscan2
- CEACAM1 | c.1314G>T p.V438= | Silent (SNP) | VAF 59/295 reads (20%) | called by muse, mutect2, varscan2
- CLCN7 | c.2055C>T p.I685= | Silent (SNP) | VAF 99/632 reads (16%) | catalogued as rs1261519602; called by muse, mutect2, varscan2
- CLPX | c.837T>C p.H279= | Silent (SNP) | VAF 29/157 reads (18%) | called by muse, mutect2, varscan2
- CMTM7 | c.478C>T p.L160= | Silent (SNP) | VAF 11/216 reads (5%) | called by muse, mutect2
- CNOT2 | c.369G>A p.T123= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as rs1387078465, COSV57502379; called by muse, mutect2, varscan2
- COL18A1 | c.2799C>T p.P933= (on ENST00000359759 / NM_130444.3; = p.P698= on NM_030582.4) | Silent (SNP) | VAF 229/552 reads (41%) | catalogued as rs914401777; called by muse, mutect2, varscan2
- COL9A2 | c.1695G>A p.G565= | Silent (SNP) | VAF 128/276 reads (46%) | called by muse, varscan2
- CPNE2 | c.394C>T p.L132= | Silent (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- CSTF2 | c.171G>A p.K57= | Silent (SNP) | VAF 62/134 reads (46%) | catalogued as rs1264249677; called by muse, mutect2, varscan2
- CYP2A7 | c.885G>A p.T295= | Silent (SNP) | VAF 22/186 reads (12%) | catalogued as rs185246293; called by muse, mutect2, varscan2
- CYP4F2 | c.1521C>T p.R507= | Silent (SNP) | VAF 100/294 reads (34%) | catalogued as rs567783827; called by muse, mutect2, varscan2
- DCAF4L2 | c.205T>C p.L69= | Silent (SNP) | VAF 36/558 reads (6%) | called by muse, mutect2
- DENND2C | c.543G>T p.L181= | Silent (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- DIAPH1 | c.2436C>T p.F812= | Silent (SNP) | VAF 26/452 reads (6%) | catalogued as rs185113837; called by muse, mutect2
- DLX2 | c.948C>T p.G316= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs1379490505, COSV52231759; called by muse, mutect2, varscan2
- DMRT3 | c.906T>C p.P302= | Silent (SNP) | VAF 36/218 reads (17%) | catalogued as rs1184437091; called by muse, mutect2, varscan2
- DNAH10 | c.9555C>T p.A3185= (on ENST00000409039; = p.A3124= on NM_207437.3) | Silent (SNP) | VAF 111/272 reads (41%) | catalogued as rs988474722; called by muse, mutect2, varscan2
- DOCK3 | c.1644C>T p.Y548= | Silent (SNP) | VAF 34/224 reads (15%) | called by muse, mutect2, varscan2
- DSP | c.2334C>A p.L778= | Silent (SNP) | VAF 46/323 reads (14%) | catalogued as COSV65791419; called by muse, mutect2, varscan2
- DYNC1H1 | c.8490G>C p.L2830= | Silent (SNP) | VAF 71/324 reads (22%) | catalogued as COSV100795581; called by muse, mutect2, varscan2
- E2F1 | c.1218C>T p.H406= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as rs553240434, COSV99865165; called by muse, mutect2, varscan2
- ELK4 | c.783G>A p.L261= | Silent (SNP) | VAF 57/340 reads (17%) | called by muse, mutect2, varscan2
- ELP6 | c.234T>C p.R78= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as rs780668754; called by muse, mutect2, varscan2
- EOMES | c.915C>T p.N305= | Silent (SNP) | VAF 90/230 reads (39%) | catalogued as rs763303684, COSV55414938, COSV55415208; called by muse, mutect2, varscan2
- EPHB1 | c.237G>A p.R79= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV67664345, COSV67665096; called by muse, mutect2
- FAM155B | c.378C>T p.P126= | Silent (SNP) | VAF 13/225 reads (6%) | catalogued as COSV52935555; called by muse, mutect2
- FAM177A1 | c.504G>A p.L168= (on ENST00000382406 / NM_001289022.2; = p.L191= on NM_173607.5) | Silent (SNP) | VAF 10/249 reads (4%) | called by muse, mutect2
- FAXC | c.96C>T p.S32= | Silent (SNP) | VAF 14/386 reads (4%) | called by muse, mutect2
- G6PC | c.534T>C p.P178= | Silent (SNP) | VAF 71/554 reads (13%) | catalogued as rs774585761; called by muse, mutect2, varscan2
- GAB3 | c.441T>A p.L147= | Silent (SNP) | VAF 114/457 reads (25%) | called by muse, mutect2, varscan2
- GALNT17 | c.714C>T p.T238= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs758291046, COSV61146047; called by muse, mutect2, varscan2
- GAMT | c.465C>T p.H155= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as rs1454250040, COSV52041050; ClinVar: likely benign; called by muse, mutect2
- GDAP1L1 | c.327T>C p.S109= | Silent (SNP) | VAF 105/236 reads (44%) | called by muse, mutect2, varscan2
- GOLGA3 | c.1038C>T p.N346= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs139919885; called by muse, mutect2, varscan2
- GRIA4 | c.1857A>G p.S619= | Silent (SNP) | VAF 15/177 reads (8%) | called by muse, mutect2
- GSTM5 | c.69C>T p.Y23= | Silent (SNP) | VAF 18/480 reads (4%) | called by muse, mutect2
- GSX1 | c.336C>T p.A112= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as rs755138087, COSV57233229; called by muse, varscan2
- HDGFL2 | c.1077C>T p.R359= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs903749032, COSV100012349; called by muse, mutect2, varscan2
- HIPK1 | c.2154C>A p.T718= | Silent (SNP) | VAF 21/259 reads (8%) | called by muse, mutect2
- HIVEP3 | c.1230C>T p.N410= | Silent (SNP) | VAF 62/161 reads (39%) | catalogued as rs199930261, COSV56016608; called by muse, mutect2, varscan2
- HMCN2 | c.4647G>A p.V1549= | Silent (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- HSP90AA1 | c.1936T>C p.L646= | Silent (SNP) | VAF 52/382 reads (14%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.1617G>A p.S539= | Silent (SNP) | VAF 83/394 reads (21%) | catalogued as rs200269024; called by muse, mutect2, varscan2
- IGSF1 | c.456C>T p.C152= | Silent (SNP) | VAF 46/155 reads (30%) | called by muse, mutect2, varscan2
- ITGB1 | c.120A>G p.Q40= | Silent (SNP) | VAF 17/150 reads (11%) | called by muse, mutect2, varscan2
- JPH3 | c.21T>C p.F7= | Silent (SNP) | VAF 187/422 reads (44%) | called by muse, mutect2, varscan2
- KCNH7 | c.3423T>C p.T1141= | Silent (SNP) | VAF 20/239 reads (8%) | catalogued as COSV59783228; called by muse, mutect2
- KCNS3 | c.333C>T p.L111= | Silent (SNP) | VAF 49/269 reads (18%) | called by muse, mutect2, varscan2
- KHDC3L | c.225C>T p.H75= | Silent (SNP) | VAF 137/321 reads (43%) | catalogued as rs749162016, COSV64869129; called by muse, mutect2, varscan2
- KIF5C | c.2565C>T p.N855= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as rs745460362, COSV68483415; called by muse, mutect2
- KMO | c.279A>G p.K93= | Silent (SNP) | VAF 42/139 reads (30%) | called by muse, mutect2, varscan2
- LHFPL1 | c.162G>A p.V54= | Silent (SNP) | VAF 33/298 reads (11%) | catalogued as rs1242287961; called by muse, mutect2, varscan2
- LMF2 | c.639C>T p.A213= | Silent (SNP) | VAF 31/199 reads (16%) | catalogued as rs776918016; called by muse, mutect2, varscan2
- LRATD2 | c.108C>T p.Y36= | Silent (SNP) | VAF 69/407 reads (17%) | catalogued as rs1342650834; called by muse, mutect2, varscan2
- LTN1 | c.447A>G p.G149= | Silent (SNP) | VAF 52/300 reads (17%) | catalogued as rs1251434069; called by muse, varscan2
- MAPK8IP1 | c.642C>T p.S214= | Silent (SNP) | VAF 43/258 reads (17%) | catalogued as rs148247913; called by muse, mutect2, varscan2
- MED12 | c.975A>G p.T325= | Silent (SNP) | VAF 33/146 reads (23%) | called by muse, mutect2, varscan2
- MED20 | c.126C>T p.D42= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as rs923195549, COSV54826655; called by muse, mutect2
- MIB1 | c.1608T>A p.I536= | Silent (SNP) | VAF 99/232 reads (43%) | called by muse, mutect2, varscan2
- MIDN | c.900G>A p.R300= | Silent (SNP) | VAF 21/211 reads (10%) | catalogued as COSV56296548; called by muse, mutect2, varscan2
- MIOS | c.1113T>C p.G371= | Silent (SNP) | VAF 21/131 reads (16%) | called by muse, mutect2, varscan2
- MPRIP | c.1143C>T p.S381= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs761626923, COSV100505571; called by muse, mutect2, varscan2
- MUC16 | c.1641A>G p.R547= | Silent (SNP) | VAF 9/195 reads (5%) | called by muse, mutect2
- MYORG | c.675C>T p.L225= | Silent (SNP) | VAF 20/543 reads (4%) | catalogued as rs1362388791, COSV52628000; called by muse, mutect2
- NEB | c.12387C>T p.S4129= | Silent (SNP) | VAF 10/254 reads (4%) | catalogued as rs1290585048, COSV51439171; called by muse, mutect2
- NEFH | c.438C>T p.Y146= | Silent (SNP) | VAF 8/198 reads (4%) | catalogued as COSV60218128; called by muse, mutect2
- NID1 | c.900C>T p.T300= | Silent (SNP) | VAF 37/478 reads (8%) | called by muse, mutect2
- NOTCH2 | c.1410C>A p.T470= | Silent (SNP) | VAF 135/553 reads (24%) | called by muse, mutect2, varscan2
- NPLOC4 | c.969T>C p.G323= | Silent (SNP) | VAF 34/130 reads (26%) | called by muse, mutect2, varscan2
- NR4A3 | c.978T>C p.Y326= | Silent (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- NT5C3B | c.474C>T p.G158= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- NUDT16L1 | c.111T>C p.P37= | Silent (SNP) | VAF 55/379 reads (15%) | called by muse, mutect2, varscan2
- OR10C1 | c.378C>T p.A126= (on ENST00000622521; = p.A124= on NM_013941.3) | Silent (SNP) | VAF 13/192 reads (7%) | called by muse, mutect2
- OR5W2 | c.603C>T p.T201= | Silent (SNP) | VAF 66/152 reads (43%) | catalogued as rs755481707, COSV60615068, COSV60617260; called by muse, mutect2, varscan2
- OTX2 | c.138T>A p.T46= (on ENST00000408990 / NM_172337.3; = p.T54= on NM_021728.4) | Silent (SNP) | VAF 37/243 reads (15%) | called by muse, mutect2, varscan2
- PAX3 | c.1017A>G p.V339= | Silent (SNP) | VAF 155/505 reads (31%) | catalogued as rs778132947; called by muse, mutect2, varscan2
- PCDH8 | c.1701C>T p.F567= | Silent (SNP) | VAF 90/212 reads (42%) | catalogued as rs1242553371; called by muse, mutect2, varscan2
- PCDHA6 | c.1671C>T p.D557= | Silent (SNP) | VAF 119/789 reads (15%) | catalogued as COSV65341441; called by muse, mutect2, varscan2
- PCDHB3 | c.783T>C p.I261= | Silent (SNP) | VAF 12/259 reads (5%) | called by muse, mutect2
- PCDHGA10 | c.1797C>T p.D599= | Silent (SNP) | VAF 77/507 reads (15%) | called by muse, mutect2, varscan2
- PCDHGB6 | c.1593G>A p.T531= | Silent (SNP) | VAF 215/420 reads (51%) | catalogued as rs764584425; called by muse, mutect2, varscan2
- PCNX2 | c.1407C>T p.G469= | Silent (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- PDZD8 | c.1902G>A p.K634= | Silent (SNP) | VAF 23/203 reads (11%) | called by muse, mutect2, varscan2
- PIK3C2B | c.4209G>A p.Q1403= | Silent (SNP) | VAF 94/614 reads (15%) | called by muse, mutect2, varscan2
- PIK3R5 | c.1995T>C p.F665= | Silent (SNP) | VAF 27/86 reads (31%) | called by muse, mutect2, varscan2
- PLA2G4E | c.1197G>T p.L399= | Silent (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- PLCXD1 | c.354G>A p.L118= | Silent (SNP) | VAF 33/209 reads (16%) | called by muse, mutect2, varscan2
- PLXNA3 | c.5164C>T p.L1722= | Silent (SNP) | VAF 8/201 reads (4%) | called by muse, mutect2
- POLD3 | c.450G>A p.S150= | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as rs200071007; called by muse, mutect2, varscan2
- POLRMT | c.9A>G p.A3= | Silent (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- POU6F2 | c.441C>T p.T147= | Silent (SNP) | VAF 128/331 reads (39%) | catalogued as COSV68873195, COSV68874385; called by muse, mutect2, varscan2
- PPIF | c.540C>T p.V180= | Silent (SNP) | VAF 101/286 reads (35%) | catalogued as rs140144301, COSV56551244; called by muse, mutect2, varscan2
- PRMT1 | c.327C>T p.A109= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as rs539807277, COSV67159293; called by muse, mutect2, varscan2
- RAB23 | c.609T>C p.G203= | Silent (SNP) | VAF 38/396 reads (10%) | called by muse, mutect2
- RAB25 | c.99G>A p.T33= | Silent (SNP) | VAF 42/149 reads (28%) | catalogued as rs373021788; called by muse, mutect2, varscan2
- RHOXF2 | c.240C>T p.G80= | Silent (SNP) | VAF 34/1127 reads (3%) | catalogued as rs782496907, COSV65047735; called by muse, mutect2
- RHPN2 | c.6C>A p.T2= | Silent (SNP) | VAF 99/249 reads (40%) | called by muse, varscan2
- RNF123 | c.2010C>T p.P670= | Silent (SNP) | VAF 85/357 reads (24%) | catalogued as rs1364431815; called by muse, mutect2, varscan2
- SALL2 | c.2451A>G p.A817= | Silent (SNP) | VAF 38/294 reads (13%) | catalogued as rs569742112; called by muse, mutect2, varscan2
- SEC24C | c.720A>G p.S240= | Silent (SNP) | VAF 33/216 reads (15%) | called by muse, mutect2, varscan2
- SFRP5 | c.246G>A p.L82= | Silent (SNP) | VAF 138/327 reads (42%) | called by muse, varscan2
- SGK2 | c.276C>G p.P92= | Silent (SNP) | VAF 33/182 reads (18%) | called by muse, mutect2, varscan2
- SH3TC1 | c.1035C>T p.C345= | Silent (SNP) | VAF 27/196 reads (14%) | catalogued as rs368425066; called by muse, mutect2, varscan2
- SLC25A29 | c.267C>T p.H89= (on ENST00000359232 / NM_001039355.3; = p.H23= on NM_152333.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 16/286 reads (6%) | catalogued as rs1312184525; called by muse, mutect2
- SLC28A2 | c.1761C>T p.V587= | Silent (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- SLC35G6 | c.60C>T p.S20= | Silent (SNP) | VAF 72/141 reads (51%) | catalogued as rs570297882; called by muse, mutect2, varscan2
- SLC39A1 | c.678C>T p.S226= | Silent (SNP) | VAF 61/519 reads (12%) | catalogued as COSV57845553; called by muse, mutect2, varscan2
- SLC39A14 | c.1110G>A p.S370= | Silent (SNP) | VAF 39/292 reads (13%) | catalogued as rs200256845, COSV99249880; called by muse, mutect2, varscan2
- SLC6A6 | c.1147C>T p.L383= | Silent (SNP) | VAF 50/293 reads (17%) | catalogued as rs770545612; called by muse, mutect2, varscan2
- SMG1 | c.9189T>C p.N3063= | Silent (SNP) | VAF 39/126 reads (31%) | called by muse, mutect2
- SOWAHD | c.654C>T p.D218= | Silent (SNP) | VAF 77/221 reads (35%) | called by muse, mutect2, varscan2
- SPATA2L | c.547C>T p.L183= | Silent (SNP) | VAF 33/145 reads (23%) | called by muse, mutect2, varscan2
- SPEG | c.7020C>T p.S2340= | Silent (SNP) | VAF 83/169 reads (49%) | catalogued as rs1247201829; called by muse, mutect2, varscan2
- SPTA1 | c.1608C>T p.D536= | Silent (SNP) | VAF 111/568 reads (20%) | catalogued as rs780560759, COSV63753929; called by muse, mutect2, varscan2
- SPTAN1 | c.7404G>A p.S2468= | Silent (SNP) | VAF 52/323 reads (16%) | catalogued as rs375649697; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- SPTB | c.279G>A p.E93= | Silent (SNP) | VAF 186/372 reads (50%) | catalogued as rs1419877128; called by muse, mutect2, varscan2
- SURF6 | c.972G>A p.R324= | Silent (SNP) | VAF 44/390 reads (11%) | catalogued as rs782228895, COSV64395216; called by muse, mutect2, varscan2
- SUV39H1 | c.1203G>A p.K401= | Silent (SNP) | VAF 32/303 reads (11%) | called by muse, mutect2, varscan2
- SYTL2 | c.921T>C p.H307= | Silent (SNP) | VAF 57/339 reads (17%) | catalogued as rs763762839, COSV60359557; called by muse, mutect2, varscan2
- TBC1D23 | c.2034T>C p.N678= (on ENST00000394144 / NM_001199198.3; = p.N663= on NM_018309.5) | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- TCP11L2 | c.39C>T p.D13= | Silent (SNP) | VAF 46/148 reads (31%) | called by muse, mutect2, varscan2
- TICAM1 | c.1278C>A p.T426= | Silent (SNP) | VAF 32/153 reads (21%) | called by muse, mutect2, varscan2
- TKTL2 | c.138G>A p.A46= | Silent (SNP) | VAF 25/152 reads (16%) | catalogued as rs764116442, COSV54920294; called by muse, mutect2, varscan2
- TM6SF1 | c.750G>A p.T250= | Silent (SNP) | VAF 13/153 reads (8%) | catalogued as rs1356161754, COSV51946498; called by muse, mutect2
- TMEM200B | c.597C>T p.P199= | Silent (SNP) | VAF 42/334 reads (13%) | catalogued as rs762118510, COSV58041114; called by muse, mutect2, varscan2
- TRGV4 | c.249A>G p.P83= | Silent (SNP) | VAF 46/359 reads (13%) | called by muse, mutect2, varscan2
- TRIO | c.3684C>T p.Y1228= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as rs1206644334; called by muse, mutect2, varscan2
- TTBK2 | c.528C>T p.D176= | Silent (SNP) | VAF 102/234 reads (44%) | catalogued as rs766215060; called by muse, mutect2, varscan2
- TWIST1 | c.141C>T p.G47= | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2
- UBE2D3 | c.300T>G p.S100= | Silent (SNP) | VAF 33/155 reads (21%) | called by muse, mutect2, varscan2
- USP22 | c.201C>T p.G67= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as rs1047038525, COSV54949498; called by muse, mutect2
- USP43 | c.2187C>T p.S729= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV53303791; called by muse, mutect2, varscan2
- VPS16 | c.1596G>T p.T532= | Silent (SNP) | VAF 42/172 reads (24%) | called by muse, mutect2, varscan2
- WDFY3 | c.8487C>T p.R2829= | Silent (SNP) | VAF 44/177 reads (25%) | catalogued as rs151109316; called by muse, mutect2, varscan2
- ZFP90 | c.1335C>T p.T445= | Silent (SNP) | VAF 27/146 reads (18%) | catalogued as rs775058659; called by muse, mutect2, varscan2
- ZNF211 | c.612C>T p.D204= (on ENST00000347302 / NM_198855.4; = p.D217= on NM_006385.5) | Silent (SNP) | VAF 26/175 reads (15%) | catalogued as rs371372624; called by muse, mutect2, varscan2
- ZNF304 | c.1056G>A p.Q352= | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- ZNF581 | c.111C>T p.S37= | Silent (SNP) | VAF 71/174 reads (41%) | called by muse, mutect2, varscan2
- ZNF710 | c.915G>A p.T305= | Silent (SNP) | VAF 27/231 reads (12%) | catalogued as rs369036930; called by muse, mutect2, varscan2
- ZNF738 | c.153C>T p.C51= | Silent (SNP) | VAF 62/157 reads (39%) | called by muse, mutect2, varscan2
- ZYG11B | c.414C>A p.L138= | Silent (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- ABCD1 | c.1082-752G>A | Intron (SNP) | VAF 118/285 reads (41%) | called by muse, mutect2, varscan2
- AC100872.1 | chr8:122670527 del A | 5'Flank (DEL) | VAF 16/96 reads (17%) | catalogued as rs750918355; called by mutect2, varscan2
- ADAMTS10 | c.*10G>C | 3'UTR (SNP) | VAF 39/253 reads (15%) | called by muse, mutect2, varscan2
- ADGRL2 | c.398-925del | Intron (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel, varscan2
- AL353804.7 | chrX:73852627 del G | 3'Flank (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- AL512625.1 | n.141_145del | RNA (DEL) | VAF 20/138 reads (14%) | called by mutect2, varscan2
- ANKUB1 | c.451+9C>T | Intron (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- AP1M1 | c.*30G>T | 3'UTR (SNP) | VAF 47/281 reads (17%) | catalogued as rs564803280, COSV99358475; called by muse, mutect2, varscan2
- APLP2 | c.105+617del | Intron (DEL) | VAF 34/181 reads (19%) | catalogued as rs1228960258; called by mutect2, pindel, varscan2
- ARMCX4 | c.1038+2088A>G | Intron (SNP) | VAF 56/359 reads (16%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+3171del | Intron (DEL) | VAF 30/232 reads (13%) | catalogued as rs760909371; called by mutect2, pindel, varscan2
- C11orf1 | chr11:111879046 T>C | 5'Flank (SNP) | VAF 27/378 reads (7%) | catalogued as rs782690801; called by muse, mutect2
- C11orf40 | n.66C>T | RNA (SNP) | VAF 85/275 reads (31%) | called by muse, mutect2, varscan2
- CCDC90B | c.468+9del | Intron (DEL) | VAF 7/32 reads (22%) | catalogued as rs113915821; called by mutect2, pindel
- CENPT | c.863-101A>G | Intron (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- CEP164 | c.393+3353T>C | Intron (SNP) | VAF 62/218 reads (28%) | called by muse, mutect2, varscan2
- CFAP45 | c.3+22del | Intron (DEL) | VAF 34/207 reads (16%) | called by mutect2, pindel, varscan2
- CLEC18B | c.785-138dup | Intron (INS) | VAF 187/1350 reads (14%) | called by mutect2, pindel, varscan2
- COLEC11 | c.203-11517G>A | Intron (SNP) | VAF 59/470 reads (13%) | called by muse, mutect2, varscan2
- CRB2 | c.3389+22del | Intron (DEL) | VAF 42/184 reads (23%) | catalogued as rs534788085; called by mutect2, pindel, varscan2
- CXCL2 | c.100+41T>C | Intron (SNP) | VAF 51/133 reads (38%) | called by muse, mutect2, varscan2
- DENND1B | c.1350+12del | Intron (DEL) | VAF 60/228 reads (26%) | called by mutect2, pindel, varscan2
- DIO3 | chr14:101558021 A>G | 5'Flank (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- DNAJC21 | c.-27A>G | 5'UTR (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2
- DNM1 | c.1335+1758G>A | Intron (SNP) | VAF 31/133 reads (23%) | called by muse, mutect2, varscan2
- DOCK4 | c.1066+49C>T | Intron (SNP) | VAF 60/357 reads (17%) | called by muse, mutect2, varscan2
- EGFR | c.1881-700G>T | Intron (SNP) | VAF 69/339 reads (20%) | called by muse, mutect2, varscan2
- EIF3B | c.*10C>T | 3'UTR (SNP) | VAF 13/93 reads (14%) | catalogued as rs757250928; called by muse, mutect2, varscan2
- ELP2 | c.523+616G>A | Intron (SNP) | VAF 89/384 reads (23%) | called by muse, mutect2
- EPB41L1 | c.1669-2823del | Intron (DEL) | VAF 112/300 reads (37%) | called by mutect2, pindel, varscan2
73 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 73 other) are not listed here.
